Gene-level copy-number profile of tumor specimen TCGA-13-0714-01A from TCGA case TCGA-13-0714, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.1 years (20,109 days).
Specimen TCGA-13-0714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e4f66c8d-3cf1-4e33-b49e-98b6ee4b98f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0714-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0fc4fc4-7bc3-48a1-8ab3-d794004c20b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 12,290; copy number 2: 38,245; copy number 3: 7,338; copy number 4: 1,132; copy number 5: 402; copy number 6: 138; copy number 7: 260.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0714-01A-01D-0356-01): tumor purity 0.76, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:94,154,193–94,187,991, 1 gene (within-gene range 0–1): GPC6-AS1.
- chr18:80,109,262–80,247,514, 5 genes: ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 800 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:23,723,262–23,904,089, 3 genes, copy number 5: ERVH-1, PPARGC1A, AC092834.1.
- chr8:65,644,734–78,805,523, 194 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:110,899,996–111,040,372, 1 gene, copy number 5 (within-gene range 4–5): LINC01608.
- chr8:111,093,263–145,066,685, 527 genes, copy number 5–7 (broad region; genes not listed).
- chr11:101,129,077–105,123,339, 74 genes, copy number 5 (broad region; genes not listed).
- chr11:105,194,440–105,194,946, 1 gene, copy number 5: OR2AL1P.

Autosomal genes at a single copy (total copy number 1): 12,290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
